Somatic mutation profile of tumor specimen MMRF_1352_1_BM_CD138pos (aliquot MMRF_1352_1_BM_CD138pos_T1_KAS5U_L00656) from MMRF case MMRF_1352, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.1 years (19,752 days).
Specimen MMRF_1352_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bbd13f7-f2cf-454c-92d5-925f3b13ac4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1352_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1352_1_PB_Whole_C2_KAS5U_L00669; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73609eb6-88b2-40cd-bd09-f4ea6459904e

The open-access MAF lists 82 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 25, Missense Mutation 25, Intron 17, Silent 7, 5'UTR 3, Frame Shift Del 2, Nonsense Mutation 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- ARHGEF17 | c.583G>C p.G195R | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as rs1238485617; called by muse, mutect2, varscan2
- ATP8B3 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs542432405; called by muse, mutect2, varscan2
- BTBD10 | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.022); catalogued as rs766063559; called by muse, mutect2, varscan2
- FSCN1 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as rs758712602; called by muse, mutect2
- IGHV2-70 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs184904469; called by muse, varscan2
- IGHV2-70 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs568191048; called by muse, varscan2
- IGHV2-70 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs372477786; called by muse, varscan2
- IGHV2-70 | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs181122105; called by muse, varscan2
- IGHV3-7 | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 62/62 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs371532793; called by muse, mutect2, varscan2
- IGLV3-1 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs762819993; called by muse, varscan2
- MUC17 | c.8968A>G p.T2990A | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60283993; called by muse, mutect2, varscan2
- PREB | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as rs1558479416; called by muse, mutect2, varscan2
- WBP1 | c.411del p.P140Lfs*10 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | catalogued as rs1433815904, COSV51970292; called by pindel, varscan2*
- AP5M1 | c.1010T>A p.I337K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- COL25A1 | c.207del p.A72Pfs*37 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, varscan2
- DOCK4 | c.3698C>G p.S1233C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- EXOC8 | c.608T>A p.V203E | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM187A | c.885G>T p.E295D | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HSPA5 | c.1659A>T p.K553N | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGHV2-70D | c.227A>C p.D76A | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- INPP5E | c.1415T>A p.V472E | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KPNB1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- MERTK | c.2436T>A p.Y812* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- POU4F1 | c.967A>C p.I323L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PXN | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SCN10A | c.4794T>G p.F1598L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTC3 | c.2735G>T p.S912I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- ATP7B | c.2997C>T p.T999= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs199581971, COSV54443894; called by muse, varscan2
- IFNW1 | c.201A>G p.K67= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- IGDCC4 | c.3594C>A p.T1198= | Silent (SNP) | VAF 30/57 reads (53%) | called by muse, mutect2, varscan2
- ITGA9 | c.705C>T p.N235= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs139839965; called by muse, mutect2, varscan2
- MS4A1 | c.12C>T p.P4= | Silent (SNP) | VAF 73/128 reads (57%) | catalogued as rs202047596, COSV61942926; called by muse, varscan2
- MYO3B | c.2541G>T p.G847= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV100509521; called by muse, mutect2, varscan2
- SCML2 | c.1059G>T p.V353= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- ACER3 | c.*1986G>A | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- AFAP1 | c.1810+29G>A | Intron (SNP) | VAF 5/30 reads (17%) | catalogued as rs768688430; called by muse, mutect2
- ANKLE2 | c.182-1469C>T | Intron (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- ANKRD36B | c.-69A>T | 5'UTR (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2
- CARF | c.832+366T>C | Intron (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- CTNS | c.*912G>A | 3'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- DIP2A | c.*1909A>T | 3'UTR (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- DMXL2 | c.*1179A>G | 3'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- DNAH10 | c.*33G>A | 3'UTR (SNP) | VAF 8/31 reads (26%) | catalogued as rs779424807, COSV53018913; called by muse, mutect2, varscan2
- EFNA5 | c.*354_*355del | 3'UTR (DEL) | VAF 27/72 reads (38%) | called by pindel, varscan2
- ESYT3 | c.*1232T>A | 3'UTR (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- ETS1 | chr11:128460099 C>A | 3'Flank (SNP) | VAF 4/24 reads (17%) | catalogued as rs774630781; called by muse, varscan2
- FAM50A | c.830-9C>T | Intron (SNP) | VAF 18/31 reads (58%) | catalogued as rs893726478; called by muse, mutect2, varscan2
- FAM71B | c.*22G>A | 3'UTR (SNP) | VAF 23/83 reads (28%) | catalogued as rs764423052, COSV57229292; called by muse, mutect2, varscan2
- GIMAP1 | c.*3125G>A | 3'UTR (SNP) | VAF 17/55 reads (31%) | catalogued as rs960989747; called by muse, mutect2, varscan2
- GNAO1 | c.-374C>T | 5'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- KLRG1 | c.559-100T>A | Intron (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- LINC02207 | n.1938T>C | RNA (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- METAP2 | c.772+11G>A | Intron (SNP) | VAF 13/69 reads (19%) | catalogued as rs1565780753; called by muse, mutect2, varscan2
- MON1B | c.*138C>G | 3'UTR (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- MUC13 | c.800+48C>A | Intron (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- OXNAD1 | c.*966G>A | 3'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- PCDH11Y | c.-697T>A | 5'UTR (SNP) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- PEX1 | c.3439-22A>C | Intron (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2
- PLCD1 | c.35-4221C>T | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- PON3 | c.778-38T>C | Intron (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- PSMD7 | c.531-14G>A | Intron (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- PSORS1C2 | c.56-271G>C | Intron (SNP) | VAF 49/95 reads (52%) | called by muse, mutect2, varscan2
- PUDP | c.511-7283G>A | Intron (SNP) | VAF 27/28 reads (96%) | catalogued as rs771236372; called by muse, mutect2, varscan2
- PUS1 | c.304-312A>T | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as rs1165329113; called by muse, varscan2
- RBM45 | c.989+47T>A | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- RBM7 | c.*821C>A | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- RHBDD1 | c.856+86A>G | Intron (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- RRAD | c.*261C>A | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- SETD7 | c.*2195G>T | 3'UTR (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- SFRP1 | c.*64C>T | 3'UTR (SNP) | VAF 11/22 reads (50%) | catalogued as rs1352571037; called by muse, mutect2, varscan2
- SH3PXD2B | c.*3050C>A | 3'UTR (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- SIK1B | c.*1688A>C | 3'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2
- SLC35D1 | c.*4210T>C | 3'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, varscan2
- SLIT3 | c.*2761G>A | 3'UTR (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- SOX9 | c.*1336C>T | 3'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- SPRY3 | c.*7463G>A | 3'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- TADA2B | c.271-954del | Intron (DEL) | VAF 22/48 reads (46%) | called by mutect2, pindel, varscan2
- TMPRSS4 | c.*1237A>T | 3'UTR (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- TPI1 | c.*201A>G | 3'UTR (SNP) | VAF 25/60 reads (42%) | catalogued as rs782508499; called by muse, mutect2, varscan2
- URB1 | c.*1120A>T | 3'UTR (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- VWA3B | c.*439T>A | 3'UTR (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
